Somatic mutation profile of tumor specimen TCGA-XF-A9T4-01A (aliquot TCGA-XF-A9T4-01A-11D-A391-08) from TCGA case TCGA-XF-A9T4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 48.5 years (17,728 days).
Specimen TCGA-XF-A9T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8d56d5f-795e-4810-bfdb-ff380aab8240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T4-10A (Blood Derived Normal), aliquot TCGA-XF-A9T4-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8020372-f2ee-4b24-8f2d-d8378de03530

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 26, Silent 8, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 65/82 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF28 | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV55270382, COSV99710277; called by muse, mutect2, varscan2
- CHIA | c.602C>T p.S201L (on ENST00000343320; = p.S93L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV58478297; called by muse, mutect2, varscan2
- CTC1 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59855522; called by muse, mutect2, varscan2
- CUX2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374906688; called by muse, mutect2, varscan2
- CYC1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs200419425, COSV59645084; called by muse, mutect2, varscan2
- EPHA7 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65191757; called by muse, mutect2, varscan2
- FN1 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs776884669, COSV60564314; called by muse, mutect2, varscan2
- GIT2 | c.1619G>C p.R540T (on ENST00000355312 / NM_057169.5; = p.R492T on NM_014776.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58085202; called by muse, mutect2, varscan2
- GJA4 | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.034); catalogued as COSV60726110; called by muse, mutect2, varscan2
- ITGAE | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV53999848; called by muse, mutect2, varscan2
- ITGAV | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1420181798, COSV53718950; called by muse, mutect2, varscan2
- KLHL1 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64784270; called by muse, mutect2, varscan2
- KLHL31 | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV100911838, COSV63882428; called by muse, mutect2, varscan2
- MRGPRX2 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as rs1470689589, COSV61674976; called by muse, mutect2, varscan2
- NAA15 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.148); catalogued as rs1230525467, COSV56722696; called by muse, mutect2, varscan2
- PCDHB4 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV52027056; called by muse, mutect2, varscan2
- PLEKHG4 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs759951391, COSV64614189; called by muse, mutect2, varscan2
- PRDM5 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 76/221 reads (34%) | catalogued as rs1455476600, COSV99311117; called by muse, mutect2, varscan2
- RGL4 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV51945404; called by muse, mutect2, varscan2
- RLF | c.4157C>G p.S1386C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV65653207; called by muse, mutect2, varscan2
- RPS6KA2 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.152); catalogued as rs779085045, COSV55820043; called by muse, mutect2, varscan2
- SEC11C | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV55312359; called by muse, mutect2, varscan2
- SMARCAD1 | c.1809-1G>C p.X603_splice | Splice Site (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100758774, COSV62776251; called by muse, mutect2, varscan2
- TFB2M | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs746323608, COSV63625169; called by muse, mutect2, varscan2
- TRRAP | c.10926G>C p.Q3642H (on ENST00000359863 / NM_001244580.1; = p.Q3613H on NM_003496.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62816818; called by muse, mutect2, varscan2
- UBA6 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.73); catalogued as COSV59174805; called by muse, mutect2, varscan2
- ZNF613 | c.622G>A p.E208K (on ENST00000293471 / NM_001031721.4; = p.E172K on NM_024840.4) | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV53273993; called by muse, mutect2, varscan2
- KMT2D | c.13801_13807dup p.G4603Afs*5 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- CD163L1 | c.2334G>A p.A778= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs201306383, COSV58016488; called by muse, mutect2, varscan2
- CDH11 | c.1062C>T p.I354= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs771089094, COSV51765224; called by muse, mutect2, varscan2
- CDR2L | c.1341C>T p.I447= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1448510920, COSV100464759; called by muse, mutect2, varscan2
- CFAP91 | c.921G>A p.Q307= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV56344770; called by muse, mutect2, varscan2
- FASTKD1 | c.2202C>T p.I734= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV71624874; called by muse, mutect2, varscan2
- PPFIBP1 | c.1329C>T p.I443= (on ENST00000318304 / NM_177444.3; = p.I426= on NM_003622.4) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1008378250, COSV57298648; called by muse, mutect2, varscan2
- STK33 | c.135A>T p.T45= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV59409543; called by muse, mutect2, varscan2
- SYNE1 | c.5427C>T p.H1809= (on ENST00000367255 / NM_182961.4; = p.H1816= on NM_033071.3) | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV55103252; called by muse, mutect2, varscan2
